Somatic mutation profile of tumor specimen TARGET-30-PAPTLV-01A (aliquot TARGET-30-PAPTLV-01A-01D) from TARGET case TARGET-30-PAPTLV, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.8 years (641 days).
Specimen TARGET-30-PAPTLV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c047cff5-c48c-4fc2-8411-b1ef43f99a12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPTLV-10A (Blood Derived Normal), aliquot TARGET-30-PAPTLV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2bd3f29-c61e-4b37-b7b0-97f679138e8a

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- ANKRD26 | c.1542G>T p.K514N | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV65796608; called by muse, mutect2, varscan2
- DOK3 | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV57253469; called by muse, mutect2, varscan2
- IL12B | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51455592; called by muse, mutect2, varscan2
- KCNC3 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65388143; called by muse, mutect2, varscan2
- STK36 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775486329, COSV55308546; called by muse, mutect2, varscan2
- ZNF683 | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV62875107; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2
- XPO4 | c.1059C>A p.T353= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
